Somatic mutation profile of tumor specimen TCGA-SX-A7SN-01A (aliquot TCGA-SX-A7SN-01A-11D-A34Z-10) from TCGA case TCGA-SX-A7SN, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 52.3 years (19,116 days).
Specimen TCGA-SX-A7SN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a37e489-6175-4f12-9484-1ba49df89f56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SX-A7SN-10A (Blood Derived Normal), aliquot TCGA-SX-A7SN-10A-01D-A34Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25ed0eb5-9142-4582-9583-db9d8cd7e53d

The open-access MAF lists 114 somatic variants for this specimen: 91 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 20, Frame Shift Del 8, Nonsense Mutation 6, Frame Shift Ins 2, 3'UTR 2, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AARS1 | c.80A>G p.H27R | Missense Mutation (SNP) | VAF 56/94 reads (60%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.985); catalogued as rs77753666, COSV99933262; called by muse, mutect2, varscan2
- ABHD14B | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201010064, COSV59986141; called by muse, mutect2, varscan2
- ALDH2 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs375845001; called by mutect2, varscan2
- ALDH2 | c.248C>A p.A83D | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99922768; called by muse, mutect2, varscan2
- ANKS6 | c.2527A>C p.I843L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.804); catalogued as COSV100782236; called by muse, mutect2, varscan2
- ARFGEF1 | c.926A>G p.K309R | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1254640307, COSV99141344; called by muse, mutect2, varscan2
- BCCIP | c.173A>T p.N58I | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as COSV99532913; called by muse, mutect2, varscan2
- C12orf43 | c.785A>G p.N262S | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV99982241; called by muse, mutect2, varscan2
- CCAR1 | c.3044C>T p.S1015L | Missense Mutation (SNP) | VAF 113/275 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99770717; called by muse, mutect2, varscan2
- CCDC144A | c.4160T>C p.L1387P | Missense Mutation (SNP) | VAF 238/997 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.902); catalogued as COSV100852736; called by muse, mutect2, varscan2
- CCDC62 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs774474363, COSV53431664; called by muse, mutect2, varscan2
- CEBPE | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1420638415, COSV99247383; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP131 | c.2450A>G p.E817G (on ENST00000269392 / NM_001319228.2; = p.E814G on NM_014984.4) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99487925; called by muse, mutect2, varscan2
- CES1 | c.958G>A p.G320S | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs138161688; called by muse, mutect2, varscan2
- CHST13 | c.335T>C p.V112A | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV100081013; called by muse, mutect2, varscan2
- CIBAR2 | c.79C>G p.Q27E | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.17); catalogued as COSV101608264; called by muse, mutect2, varscan2
- CLK4 | c.187A>G p.N63D | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.98); catalogued as COSV100308849; called by muse, mutect2, varscan2
- CLTA | c.404G>A p.W135* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as COSV99643554; called by muse, mutect2, varscan2
- CTCFL | c.546C>T p.L182= | Splice Region (SNP) | VAF 66/157 reads (42%) | catalogued as COSV99712254; called by muse, mutect2, varscan2
- EEF1A1 | c.626C>A p.P209H | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV100303223; called by muse, mutect2, varscan2
- EIF4A1 | c.1061A>G p.E354G | Missense Mutation (SNP) | VAF 69/124 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99548779; called by muse, mutect2, varscan2
- ENTPD8 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as COSV100395472; called by muse, mutect2, varscan2
- FHDC1 | c.3398C>T p.T1133M | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV99471094; called by muse, mutect2, varscan2
- FSCN2 | c.1214A>G p.N405S | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV100585256; called by muse, mutect2, varscan2
- GADD45B | c.405G>C p.L135F | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV99297999; called by muse, mutect2, varscan2
- HIKESHI | c.269G>C p.G90A | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.179); catalogued as COSV99563297; called by muse, mutect2, varscan2
- HMOX2 | c.455A>G p.H152R | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99566385; called by muse, mutect2, varscan2
- HNRNPAB | c.357dup p.D120Rfs*22 | Frame Shift Ins (INS) | VAF 47/131 reads (36%) | catalogued as rs761030612; called by mutect2, pindel, varscan2
- ICE2 | c.1589T>A p.M530K | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV99831347; called by muse, mutect2, varscan2
- IFT22 | c.439C>A p.H147N | Missense Mutation (SNP) | VAF 85/226 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV100190014; called by muse, mutect2, varscan2
- ITGA10 | c.46C>A p.L16M | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV100994764; called by muse, mutect2, varscan2
- ITGA6 | c.1930C>T p.P644S (on ENST00000442250; = p.P605S on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99905203; called by muse, mutect2, varscan2
- KIF27 | c.932A>G p.K311R | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1341746414, COSV99926778; called by muse, mutect2, varscan2
- KLHL30 | c.1394G>C p.R465P | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs767538722, COSV100014065, COSV59975399, COSV59977403; called by muse, mutect2, varscan2
- KNTC1 | c.5153G>A p.W1718* | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | catalogued as COSV100338030; called by muse, mutect2, varscan2
- KNTC1 | c.5154G>T p.W1718C | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100338032; called by muse, mutect2, varscan2
- KSR1 | c.1265A>G p.H422R (on ENST00000644974 / NM_001367810.1; = p.H285R on NM_014238.2) | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.287); catalogued as rs1490624272, COSV99258525; called by muse, mutect2, varscan2
- METTL22 | c.1057G>T p.D353Y | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs745452183, COSV99371572; called by muse, mutect2, varscan2
- MLXIPL | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV100515205; called by muse, mutect2, varscan2
- MTERF2 | c.644A>T p.Q215L | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99526717; called by muse, mutect2, varscan2
- MZT2B | c.440del p.G147Afs*? | Frame Shift Del (DEL) | VAF 40/117 reads (34%) | catalogued as rs772879277; called by mutect2, varscan2
- NAB1 | c.558G>T p.E186D | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV100492902; called by muse, mutect2, varscan2
- NRDC | c.1906A>G p.M636V | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100703170; called by muse, mutect2, varscan2
- NSL1 | c.302A>G p.N101S | Missense Mutation (SNP) | VAF 85/253 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs1270246141, COSV100875195; called by muse, mutect2, varscan2
- OR2T1 | c.693G>C p.E231D | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as COSV100822265, COSV63542900; called by muse, mutect2, varscan2
- PCDHA13 | c.1756G>T p.G586C | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV56486094, COSV99165391; called by muse, mutect2, varscan2
- PIK3R5 | c.2357C>A p.S786Y | Missense Mutation (SNP) | VAF 113/213 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); catalogued as COSV99353008; called by muse, mutect2, varscan2
- PIK3R5 | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.631); catalogued as rs753871554, COSV99353011; called by muse, mutect2, varscan2
- PKHD1 | c.1233G>T p.K411N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100581670; called by muse, mutect2, varscan2
- PTBP2 | c.1520T>C p.M507T (on ENST00000426398 / NM_001300986.2; = p.M498T on NM_021190.4) | Missense Mutation (SNP) | VAF 75/235 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100930187; called by muse, mutect2, varscan2
- QRICH1 | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 33/85 reads (39%) | catalogued as COSV100676700; called by muse, mutect2, varscan2
- QRSL1 | c.1348C>A p.Q450K | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100945392; called by muse, varscan2
- RAB20 | c.54G>C p.K18N | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99940821; called by muse, mutect2, varscan2
- RAET1E | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV100593447; called by muse, mutect2, varscan2
- RORA | c.668T>C p.L223P (on ENST00000335670 / NM_134261.3; = p.L248P on NM_002943.3) | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV99832298; called by muse, mutect2, varscan2
- SEC24C | c.2491T>G p.C831G | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1293761869, COSV100226587; called by muse, mutect2, varscan2
- SEL1L2 | c.2017G>A p.G673S | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.014); catalogued as COSV99532763; called by muse, mutect2, varscan2
- SERPINA3 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as rs1469951475, COSV101261628; called by muse, mutect2, varscan2
- SETD3 | c.835C>G p.H279D | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100074895; called by muse, mutect2, varscan2
- SIRT7 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100155440; called by muse, mutect2, varscan2
- SLC22A7 | c.1091T>C p.L364P (on ENST00000372585 / NM_153320.2; = p.L362P on NM_006672.3) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV99240181; called by muse, mutect2, varscan2
- SLC30A1 | c.502A>G p.T168A | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100879105; called by muse, mutect2, varscan2
- SLC5A12 | c.842T>C p.L281P | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99744549; called by muse, mutect2, varscan2
- SMC6 | c.2365C>T p.Q789* | Nonsense Mutation (SNP) | VAF 118/281 reads (42%) | catalogued as COSV100704851; called by muse, mutect2, varscan2
- SMCR8 | c.1430C>T p.T477M | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs571482412, COSV100328962; called by muse, varscan2
- SNX27 | c.439G>C p.D147H | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100918984; called by muse, mutect2, varscan2
- SPTBN1 | c.4985G>C p.S1662T | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV100441985; called by muse, mutect2, varscan2
- SRBD1 | c.2175T>G p.N725K | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.808); catalogued as COSV99764795; called by muse, mutect2, varscan2
- STX17 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV99407881; called by muse, mutect2, varscan2
- SYMPK | c.233T>C p.I78T | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as COSV99841467; called by muse, mutect2, varscan2
- SYNE3 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs758563267, COSV100515709; called by muse, mutect2, varscan2
- SYNPO2 | c.122A>C p.K41T | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100205086; called by muse, varscan2
- THOC2 | c.2144A>G p.Y715C | Missense Mutation (SNP) | VAF 47/61 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99832916; called by muse, mutect2, varscan2
- TMBIM1 | c.926A>G p.D309G | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99297825; called by muse, mutect2, varscan2
- TP53BP1 | c.3550A>G p.T1184A | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as rs938565935, COSV99779999; called by muse, mutect2, varscan2
- TRIP12 | c.3731G>A p.G1244E | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99389583; called by muse, mutect2, varscan2
- WDFY3 | c.484G>C p.D162H | Missense Mutation (SNP) | VAF 82/224 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99882445; called by muse, mutect2, varscan2
- XYLB | c.541C>A p.Q181K | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV99264033; called by muse, mutect2, varscan2
- ZNF282 | c.17C>A p.T6K | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV100021479; called by muse, mutect2, varscan2
- ZNF283 | c.272A>T p.D91V | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); catalogued as COSV100161326; called by muse, mutect2, varscan2
- ZNF649 | c.1039G>T p.G347* | Nonsense Mutation (SNP) | VAF 30/78 reads (38%) | catalogued as COSV100030857; called by muse, mutect2, varscan2
- EPS8L1 | c.933del p.S312Rfs*44 (on ENST00000201647 / NM_133180.3; = p.S185Rfs*44 on NM_017729.3) | Frame Shift Del (DEL) | VAF 35/109 reads (32%) | called by mutect2, pindel, varscan2
- ERICH3 | c.1290del p.V431* | Frame Shift Del (DEL) | VAF 144/439 reads (33%) | called by mutect2, pindel, varscan2
- GUCY2C | c.1262del p.P421Lfs*12 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | called by mutect2, pindel, varscan2
- SLC9A4 | c.935del p.L312Cfs*4 | Frame Shift Del (DEL) | VAF 63/237 reads (27%) | called by mutect2, pindel, varscan2
- SMCR8 | c.1419del p.V474Ffs*24 | Frame Shift Del (DEL) | VAF 14/55 reads (25%) | called by pindel, varscan2
- SPAG17 | c.6483dup p.I2162Yfs*8 | Frame Shift Ins (INS) | VAF 48/151 reads (32%) | called by mutect2, pindel, varscan2
- UTP25 | c.879_886del p.F293Lfs*35 | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | called by mutect2, pindel, varscan2
- VPS52 | c.1667del p.S556* | Frame Shift Del (DEL) | VAF 20/73 reads (27%) | called by mutect2, pindel, varscan2
- ZNF26 | c.1566T>A p.N522K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, varscan2
- ZNF26 | c.1583A>C p.H528P | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- AKAP13 | c.1347C>T p.D449= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as COSV100773237; called by muse, mutect2, varscan2
- AL592490.1 | c.2112G>A p.Q704= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as COSV101308124, COSV69426207; called by muse, mutect2, varscan2
- ASB13 | c.534G>A p.A178= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as rs773025787, COSV100731338; called by muse, mutect2, varscan2
- E2F4 | c.162G>A p.Q54= | Silent (SNP) | VAF 35/68 reads (51%) | catalogued as rs143700278; called by muse, mutect2, varscan2
- EBNA1BP2 | c.162G>A p.K54= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as COSV99355856; called by muse, mutect2, varscan2
- FEM1C | c.1756T>C p.L586= | Silent (SNP) | VAF 53/139 reads (38%) | catalogued as rs1173617526, COSV99174353; called by muse, mutect2, varscan2
- GRHL1 | c.1770T>C p.I590= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV100257610; called by muse, mutect2, varscan2
- IPMK | c.327T>C p.Y109= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV100880246; called by muse, mutect2, varscan2
- IQGAP2 | c.3426C>T p.A1142= | Silent (SNP) | VAF 36/97 reads (37%) | catalogued as COSV99166815; called by muse, mutect2, varscan2
- KMT2D | c.1836T>C p.P612= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV99978487; called by muse, mutect2, varscan2
- MAGI3 | c.1446C>T p.V482= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV100288336; called by muse, mutect2, varscan2
- MYH10 | c.4959G>A p.Q1653= | Silent (SNP) | VAF 152/289 reads (53%) | catalogued as COSV99344426; called by muse, mutect2, varscan2
- NAV2 | c.3045A>G p.S1015= (on ENST00000396087 / NM_001244963.2; = p.S992= on NM_145117.5) | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV100216360; called by muse, mutect2, varscan2
- NBAS | c.5580T>A p.P1860= | Silent (SNP) | VAF 41/88 reads (47%) | catalogued as COSV55740465; called by muse, mutect2, varscan2
- NR1D1 | c.1738T>C p.L580= | Silent (SNP) | VAF 55/78 reads (71%) | catalogued as COSV99225334; called by muse, mutect2, varscan2
- PLEKHH2 | c.2889T>C p.P963= | Silent (SNP) | VAF 163/442 reads (37%) | catalogued as COSV99174414; called by muse, mutect2, varscan2
- RP1 | c.1218G>A p.E406= | Silent (SNP) | VAF 34/89 reads (38%) | catalogued as COSV99606580; called by muse, mutect2, varscan2
- SMAP1 | c.57C>A p.L19= | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as COSV100390869, COSV57641267; called by muse, mutect2, varscan2
- TGIF1 | c.465T>C p.H155= (on ENST00000330513 / NM_001374396.1; = p.H175= on NM_003244.4) | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as rs1471865538, COSV100394739; called by muse, mutect2, varscan2
- ZKSCAN5 | c.633C>T p.S211= | Silent (SNP) | VAF 33/64 reads (52%) | catalogued as COSV100460055; called by muse, mutect2, varscan2
- FBXL21P | n.675T>A | RNA (SNP) | VAF 91/212 reads (43%) | catalogued as COSV99778222; called by muse, mutect2, varscan2
- NPR3 | c.*3266A>G | 3'UTR (SNP) | VAF 41/94 reads (44%) | catalogued as COSV99422469; called by muse, mutect2, varscan2
- TDRD10 | c.*134A>T | 3'UTR (SNP) | VAF 61/159 reads (38%) | catalogued as COSV99427282; called by muse, mutect2, varscan2
